Gene-level copy-number profile of tumor specimen ALCH-B4IG-TTP1-A from ALCHEMIST case ALCH-B4IG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.1 years (19,399 days).
Specimen ALCH-B4IG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cb2ab9ca-331a-4149-a860-3d2dc7d1536a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4IG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/07ed6214-6a52-4ce3-8734-c7d9c4034e8d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 1,840; copy number 2: 52,204; copy number 3: 3,592; copy number 4: 558; copy number 5: 158; copy number 6: 15; copy number 9: 26; copy number 10: 1; copy number 11: 1; copy number 23: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:134,673,131–134,673,512, 1 gene (within-gene range 0–3): AC087045.1.
- chr18:43,267,892–43,277,535, 1 gene: SYT4.
- chr19:39,196,964–39,204,263, 2 genes: NCCRP1, SYCN.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 170 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:66,485,095–66,592,397, 8 genes, copy number 5 (within-gene range 2–5): AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1.
- chr7:76,650,401–79,544,853, 47 genes, copy number 5 (within-gene range 5–7): AC004980.2, AC006972.1, AC007003.1, DTX2P1-UPK3BP1-PMS2P11, FDPSP7, AC114737.1, DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17, PMS2P9, Y_RNA, AC007000.3, SPDYE18, AC007000.2, FAM185BP, AC007000.1, CCDC146, FGL2, AC098851.1, GSAP, AC004921.1, GCNT1P5, PTPN12, APTR, RSBN1L, TMEM60, PHTF2, Y_RNA, AC004990.1, MAGI2, AC004808.2, AC004808.1, RPL13AP17, AC006043.1, AC007237.1, MAGI2-AS1, MAGI2-AS2, RNU6-337P, AC006355.1, AC006355.2, AC074024.1, RNU6-530P, AC004945.1, MAGI2-AS3, NUP35P2.
- chr12:57,723,761–57,742,157, 1 gene, copy number 5 (within-gene range 3–5): AGAP2.
- chr12:57,738,013–58,395,138, 28 genes, copy number 5: TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1.
- chr12:61,231,159–62,279,150, 5 genes, copy number 6 (within-gene range 2–6): AC090017.1, DUX4L52, TAFA2, RPL21P104, KRT8P19.
- chr12:64,759,496–64,977,509, 1 gene, copy number 5 (within-gene range 2–5): AC078815.1.
- chr12:64,883,394–65,248,355, 9 genes, copy number 5: LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2.
- chr12:66,066,221–67,753,817, 29 genes, copy number 5: RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1.
- chr12:68,808,177–68,850,686, 2 genes, copy number 9 (within-gene range 4–9): MDM2, AC025423.1.
- chr12:75,964,440–75,967,062, 2 genes, copy number 6 (within-gene range 2–6): AC011611.2, AC011611.1.
- chr16:67,326,798–67,719,339, 25 genes, copy number 9–10: LRRC36, TPPP3, RNU1-123P, ZDHHC1, HSD11B2, AC009061.1, ATP6V0D1, AC009061.2, AGRP, AC027682.6, RIPOR1, AC027682.5, AC027682.2, AC027682.3, AC027682.4, AC027682.7, AC027682.1, CTCF, AC009095.1, CARMIL2, ACD, PARD6A, ENKD1, C16orf86, GFOD2.
- chr16:90,056,566–90,222,851, 8 genes, copy number 6: PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr17:2,054,154–2,063,241, 1 gene, copy number 23 (within-gene range 2–23): HIC1.
- chr19:1,021,522–1,039,068, 3 genes, copy number 5: RNU6-2, CNN2, AC011558.1.
- chr22:50,263,713–50,270,767, 1 gene, copy number 11: MAPK11.

Autosomal genes at a single copy (total copy number 1): 1,840. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
